Somatic mutation profile of tumor specimen TCGA-CI-6620-01A (aliquot TCGA-CI-6620-01A-11D-1826-10) from TCGA case TCGA-CI-6620, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IVA; Age at diagnosis: 41.9 years (15,322 days).
Specimen TCGA-CI-6620-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aa47b540-d9e9-4489-99af-db073d13ecf5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CI-6620-10A (Blood Derived Normal), aliquot TCGA-CI-6620-10A-01D-1826-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/90b8a87e-b73f-45cf-8f42-6d1cf111eefb

The open-access MAF lists 63 somatic variants for this specimen: 41 protein-altering or splice-affecting, 22 silent.
By variant classification: Missense Mutation 34, Silent 22, Frame Shift Ins 3, Frame Shift Del 2, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2626C>T p.R876* | Nonsense Mutation (SNP) | VAF 26/57 reads (46%) | hotspot (GDC flag); catalogued as rs121913333, CM942020, COSV57320538; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 91/214 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB10 | c.1786T>C p.S596P | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.611); catalogued as COSV100747997; called by muse, mutect2, varscan2
- ABCB10 | c.1390C>T p.R464C | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as rs975781231, COSV60622177; called by muse, mutect2, varscan2
- ADGRG7 | c.725C>T p.S242F | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); catalogued as COSV56300140; called by muse, mutect2, varscan2
- ASTN2 | c.910C>T p.R304W | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.727); catalogued as rs554132287, COSV57804953; called by muse, mutect2, varscan2
- ATP2A1 | c.1712dup p.K572Efs*9 | Frame Shift Ins (INS) | VAF 10/32 reads (31%) | catalogued as rs772363145; called by mutect2, varscan2
- CDH23 | c.559G>A p.V187I | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0.014); catalogued as rs369624952; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDH5 | c.1697C>T p.T566M | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs769543281, COSV58518275; called by muse, mutect2, varscan2
- CHST2 | c.541G>A p.G181S | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58884666; called by muse, mutect2, varscan2
- COL6A3 | c.6769G>A p.A2257T | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs372154635; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CREBBP | c.4134-1G>A p.X1378_splice | Splice Site (SNP) | VAF 11/53 reads (21%) | catalogued as COSV52133688; called by muse, mutect2, varscan2
- DLC1 | c.1969G>A p.E657K (on ENST00000276297 / NM_001348081.2; = p.E220K on NM_006094.5) | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.194); catalogued as COSV52298208; called by muse, mutect2, varscan2
- DPP6 | c.2546T>C p.I849T (on ENST00000377770 / NM_001364500.2; = p.I787T on NM_001936.5) | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0.07); catalogued as COSV59638310; called by muse, mutect2, varscan2
- DUS1L | c.694G>A p.A232T | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs114350519, COSV57651002; called by mutect2, varscan2
- GABPA | c.551A>G p.Y184C | Missense Mutation (SNP) | VAF 74/255 reads (29%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.91); catalogued as rs749270145, COSV61397307; called by muse, mutect2, varscan2
- GSK3A | c.1115C>T p.T372M | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.999); catalogued as rs1295983715, COSV99725344; called by muse, mutect2
- IL6ST | c.2740G>A p.G914S | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs1337649433, COSV100410911, COSV61142563; called by muse, mutect2, varscan2
- INKA2 | c.563G>A p.R188H | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.205); catalogued as rs371956554; called by muse, mutect2, varscan2
- KIF1A | c.5044G>A p.G1682R (on ENST00000320389 / NM_001379639.1; = p.G1674R on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781422815, COSV57498588; called by muse, mutect2, varscan2
- LENG8 | c.1387C>T p.R463W | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs750373164, COSV58729742; called by muse, mutect2, varscan2
- MCFD2 | c.28C>G p.P10A | Missense Mutation (SNP) | VAF 52/77 reads (68%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.014); catalogued as COSV60178361; called by muse, mutect2, varscan2
- MDC1 | c.5699T>C p.V1900A | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV64526598; called by muse, mutect2, varscan2
- MRGPRX1 | c.893C>T p.A298V | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs183845903, COSV57106525; called by muse, mutect2, varscan2
- MUC16 | c.8838G>T p.K2946N | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.82); catalogued as COSV101200317, COSV67468127; called by muse, mutect2
- NADK2 | c.1291A>G p.K431E (on ENST00000381937 / NM_001085411.3; = p.K268E on NM_153013.4) | Missense Mutation (SNP) | VAF 32/182 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99237607; called by muse, varscan2
- NPAP1 | c.637T>C p.Y213H | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV61507183, COSV61510285; called by muse, mutect2, varscan2
- OR5W2 | c.487G>T p.A163S | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.41); catalogued as COSV60617959, COSV60618430; called by muse, mutect2, varscan2
- PADI1 | c.971A>G p.D324G | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.338); catalogued as COSV64939080; called by muse, mutect2, varscan2
- SAT1 | c.362G>A p.R121H | Missense Mutation (SNP) | VAF 21/137 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as rs1363595764, COSV63380787; called by muse, mutect2, varscan2
- SMARCA4 | c.400G>A p.V134I | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.018); catalogued as COSV100758721; called by muse, mutect2, varscan2
- SPG21 | c.499A>C p.N167H | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.63); catalogued as COSV52603734; called by muse, mutect2, varscan2
- TAF1L | c.4461G>T p.Q1487H | Missense Mutation (SNP) | VAF 106/340 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.153); catalogued as COSV99644919; called by muse, mutect2, varscan2
- TTN | c.40385G>T p.R13462L (on ENST00000591111; = p.R6038L on NM_003319.4) | Missense Mutation (SNP) | VAF 38/133 reads (29%) | PolyPhen possibly damaging (0.671); catalogued as COSV59942386, COSV60323737; called by muse, mutect2, varscan2
- TWSG1 | c.325G>C p.E109Q | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as COSV50815575; called by muse, mutect2, varscan2
- ZNF208 | c.2669A>T p.K890I | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV68111275; called by muse, mutect2, varscan2
- ZNF257 | c.1187G>C p.R396T | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV71311125, COSV71312851; called by muse, mutect2, varscan2
- ZNF528 | c.450_451insC p.I151Hfs*12 | Frame Shift Ins (INS) | VAF 7/46 reads (15%) | catalogued as COSV64620790; called by mutect2, pindel, varscan2
- CRX | c.692del p.G231Afs*140 | Frame Shift Del (DEL) | VAF 6/35 reads (17%) | called by mutect2, pindel, varscan2
- FBXW7 | c.1475del p.Q492Rfs*6 (on ENST00000281708 / NM_001349798.2; = p.Q412Rfs*6 on NM_018315.5) | Frame Shift Del (DEL) | VAF 39/100 reads (39%) | called by mutect2, pindel, varscan2
- TP53 | c.695_698dup p.Y234Pfs*7 | Frame Shift Ins (INS) | VAF 15/42 reads (36%) | called by mutect2, varscan2
- ADAMTS8 | c.2544C>T p.C848= | Silent (SNP) | VAF 27/68 reads (40%) | catalogued as rs776676907, COSV57296303, COSV99960750; called by muse, mutect2, varscan2
- CAMK2A | c.1275G>A p.E425= (on ENST00000348628 / NM_171825.2; = p.E436= on NM_015981.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/73 reads (15%) | catalogued as COSV62247396; called by muse, mutect2, varscan2
- CARNMT1 | c.516T>A p.T172= | Silent (SNP) | VAF 21/110 reads (19%) | catalogued as COSV65190673; called by muse, mutect2, varscan2
- COL9A3 | c.1101C>T p.G367= | Silent (SNP) | VAF 53/98 reads (54%) | catalogued as rs765090954, COSV59655183; called by muse, mutect2, varscan2
- GNG4 | c.198C>T p.R66= | Silent (SNP) | VAF 18/47 reads (38%) | catalogued as rs1037180132, COSV64000206; called by muse, mutect2, varscan2
- GPT2 | c.1320C>T p.Y440= | Silent (SNP) | VAF 22/67 reads (33%) | catalogued as rs753982355, COSV60839833; called by muse, mutect2, varscan2
- GUSB | c.495G>T p.R165= | Silent (SNP) | VAF 35/104 reads (34%) | catalogued as COSV59223374; called by muse, mutect2, varscan2
- IRX1 | c.342G>A p.A114= | Silent (SNP) | VAF 12/73 reads (16%) | catalogued as COSV57361821; called by muse, mutect2, varscan2
- KSR2 | c.384C>T p.C128= | Silent (SNP) | VAF 13/72 reads (18%) | catalogued as rs371982174; called by muse, mutect2, varscan2
- MAB21L2 | c.804G>A p.P268= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as rs374360655, COSV100462027, COSV58263156; called by muse, mutect2, varscan2
- MYBL1 | c.795A>G p.E265= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as COSV101576564; called by muse, mutect2, varscan2
- NLRP12 | c.2778C>T p.G926= | Silent (SNP) | VAF 21/58 reads (36%) | catalogued as COSV60753009; called by muse, mutect2, varscan2
- PCDHGA3 | c.810C>T p.D270= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as rs547334260, COSV53900873; called by muse, mutect2, varscan2
- PRKCB | c.1413C>T p.N471= | Silent (SNP) | VAF 34/110 reads (31%) | catalogued as rs745373140, COSV100331820; called by muse, varscan2
- RPGR | c.1623C>T p.N541= | Silent (SNP) | VAF 91/311 reads (29%) | catalogued as rs769507521, COSV58838901; called by muse, mutect2, varscan2
- SETD1A | c.4383C>T p.N1461= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as rs368388561; called by muse, mutect2, varscan2
- SLC66A3 | c.204G>A p.E68= | Silent (SNP) | VAF 14/86 reads (16%) | catalogued as rs764046320, COSV54468116; called by muse, mutect2, varscan2
- SUPT5H | c.2931C>T p.S977= | Silent (SNP) | VAF 21/59 reads (36%) | catalogued as rs760484241, COSV63241575; called by muse, mutect2, varscan2
- SYNE1 | c.4243C>T p.L1415= (on ENST00000367255 / NM_182961.4; = p.L1422= on NM_033071.3) | Silent (SNP) | VAF 70/202 reads (35%) | catalogued as COSV55088264; called by muse, mutect2, varscan2
- THOC2 | c.1788T>A p.P596= | Silent (SNP) | VAF 70/287 reads (24%) | catalogued as COSV55553503; called by muse, mutect2, varscan2
- XPOT | c.315C>T p.A105= | Silent (SNP) | VAF 51/211 reads (24%) | catalogued as rs372746587; called by muse, mutect2, varscan2
- ZNF628 | c.2202G>A p.P734= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as COSV52701791; called by muse, mutect2, varscan2
